TCGA case TCGA-B0-4814 — Kidney Renal Clear Cell Carcinoma (TCGA-KIRC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/420409bb-0889-40a1-80cf-9b5916704f04

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 58 years; Vital status: Dead; Days to death: 168 days.

Diagnoses (1)
1. Clear cell adenocarcinoma, NOS: ICD-O-3 morphology code: 8310/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 58.5 years (21,374 days); Year of diagnosis: 2001; AJCC pathologic T: T4; AJCC pathologic N: N0; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.

Follow-up (1 entry)
- Days to follow up: 168 days; Disease response: With Tumor.

Molecular and laboratory tests
- Hemoglobin: Low.
- Leukocytes: Elevated.
- Platelets: Normal.
- Calcium: Low.

Exposures
- Exposure type: Tobacco.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-B0-4814-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 2.5; Intermediate dimension: 1.7; Shortest dimension: 0.2.
  Slide TCGA-B0-4814-01A-01-BS1: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15.
  Slide TCGA-B0-4814-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15.
- Sample TCGA-B0-4814-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-B0-4814-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.5; Intermediate dimension: 1; Shortest dimension: 0.3.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Clear Cell Renal Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Serum calcium level: Low; Hemoglobin level: Low; Lymph nodes examined: No.
- Follow-up form: Tumor status: With tumor; Performance status timing: At Recurrence/Progression Of Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 168 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 168 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 168 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-B0-4814-01): tumor purity 0.47, ploidy 4.03, whole-genome doublings 1 (call status: legacy_call).
